Somatic mutation profile of tumor specimen 0DVR7V from CCDI case PBCMWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 3.4 years (1,243 days).
Specimen 0DVR7V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405adb34-70b8-4ae4-ad2d-9f3913edf97e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb5d0bde-f103-4382-bd56-3f6860aadb1c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 170/612 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- CFAP47 | c.4504A>C p.S1502R | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as COSV100545007; called by muse, mutect2
- EEF1AKMT4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 96/648 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs762800634, COSV56182038; called by muse, mutect2, varscan2
- MALRD1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 67/649 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs865934995; called by muse, mutect2, varscan2
- OR13H1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 131/594 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as rs775432261, COSV100088386; called by muse, mutect2, varscan2
- MED12L | c.3447C>A p.G1149= | Splice Region (SNP) | VAF 96/710 reads (14%) | called by muse, mutect2, varscan2
- RYR2 | c.9260C>G p.P3087R | Missense Mutation (SNP) | VAF 23/470 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); called by muse, mutect2
- TTN | c.38897G>C p.C12966S (on ENST00000591111; = p.C5542S on NM_003319.4) | Missense Mutation (SNP) | VAF 136/691 reads (20%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZSWIM4 | c.1250T>A p.I417N | Missense Mutation (SNP) | VAF 60/676 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CNBD1 | c.765C>T p.D255= | Silent (SNP) | VAF 44/608 reads (7%) | catalogued as COSV72975993; called by muse, mutect2
- REXO5 | c.957G>A p.L319= | Silent (SNP) | VAF 113/468 reads (24%) | catalogued as COSV54474941; called by muse, mutect2, varscan2
- RIOX1 | c.852C>T p.A284= | Silent (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 20/448 reads (4%) | called by muse, mutect2
